CCDI case PBCCKA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/c3ef70ce-6e64-48c9-8c61-1393b8c2e0e2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 16.9 years (6,160 days).

Biospecimens (3 samples)
- Sample 0DOLUS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOLVB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOLVX: Tissue type: Tumor; Specimen type: Solid Tissue.
